Gene-level copy-number profile of tumor specimen TCGA-FR-A7U9-06A from TCGA case TCGA-FR-A7U9, project TCGA-SKCM (Skin Cutaneous Melanoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Malignant melanoma, NOS; Tissue or organ of origin: Skin, NOS; Age at diagnosis: 63.8 years (23,295 days).
Specimen TCGA-FR-A7U9-06A: Sample type: Metastatic; Tissue type: Tumor; Tumor descriptor: Metastatic.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-SKCM.21d0508c-d88b-4285-8b8a-9b881d5c5051.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-FR-A7U9-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 803 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/b36484e2-c1f3-4fb1-a74a-1f9f23b3d63a

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 74; copy number 1: 5,603; copy number 2: 52,059; copy number 3: 2,084.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-FR-A7U9-06A-11D-A34T-01): tumor purity 0.28, ploidy 4.18, whole-genome doublings 2.

Homozygous deletions (total copy number 0; autosomes only): 74 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr6:166,409,364–166,906,451, 1 gene (within-gene range 0–1): RPS6KA2.
- chr6:166,651,524–169,781,600, 73 genes (within-gene range 0–1) (broad region; genes not listed).

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): none.

Autosomal genes at a single copy (total copy number 1): 5,544. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
